Somatic mutation profile of tumor specimen TARGET-10-PATYMP-09A (aliquot TARGET-10-PATYMP-09A-01D) from TARGET case TARGET-10-PATYMP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.5 years (6,742 days).
Specimen TARGET-10-PATYMP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cf050cb-d6fc-4a73-b6c5-66223acf9604.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATYMP-10A (Blood Derived Normal), aliquot TARGET-10-PATYMP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f4acfee-4dcd-436c-a774-c66ddd40f173

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 3, Splice Site 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1435C>T p.R479* (on ENST00000281708 / NM_001349798.2; = p.R399* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | hotspot (GDC flag); catalogued as COSV55894141, COSV55894999, COSV55908957; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANO4 | c.2747G>A p.R916Q (on ENST00000392977 / NM_001286615.2; = p.R881Q on NM_178826.4) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs267603265, COSV54611712; called by muse, mutect2
- CX3CL1 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.401); catalogued as rs779792519, COSV50055742; called by muse, mutect2, varscan2
- FAT3 | c.6794C>T p.T2265I | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1326044489, COSV53177639; called by muse, mutect2, varscan2
- FSTL5 | c.2533G>T p.G845* | Nonsense Mutation (SNP) | VAF 30/60 reads (50%) | catalogued as COSV60232603; called by muse, mutect2, varscan2
- MMP16 | c.1135A>G p.M379V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs142006673; called by muse, mutect2, varscan2
- MTFR1L | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV65356561; called by muse, mutect2, varscan2
- OGT | c.219-1G>A p.X73_splice | Splice Site (SNP) | VAF 32/38 reads (84%) | catalogued as COSV65482768; called by muse, mutect2, varscan2
- OR5A2 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV57391975; called by muse, mutect2, varscan2
- PCSK6 | c.2038+1G>A p.X680_splice | Splice Site (SNP) | VAF 13/34 reads (38%) | catalogued as COSV61861418; called by muse, mutect2, varscan2
- ZNF620 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- C4orf51 | c.498G>A p.K166= | Silent (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- KCNS3 | c.807G>A p.T269= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs778207777, COSV58406596; called by muse, mutect2, varscan2
- ZIC1 | c.807C>T p.H269= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV99292264; called by muse, mutect2, varscan2
- GABRB2 | c.237+135C>T | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- NCR1 | c.*85C>T | 3'UTR (SNP) | VAF 14/36 reads (39%) | catalogued as rs561654531; called by muse, mutect2, varscan2
